Somatic mutation profile of tumor specimen TCGA-AA-3531-01A (aliquot TCGA-AA-3531-01A-01D-1953-10) from TCGA case TCGA-AA-3531, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 75.3 years (27,514 days).
Specimen TCGA-AA-3531-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d7a81ed-6fc6-4b2e-a18e-ac3707dc4f2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3531-10A (Blood Derived Normal), aliquot TCGA-AA-3531-10A-01D-1953-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60414e75-160f-4ba1-8d2c-ef518cf1907b

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 10, Silent 5, Nonsense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC124 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.628); catalogued as rs1203547783, COSV101506477; called by muse, mutect2, varscan2
- COL4A1 | c.1747G>T p.G583* | Nonsense Mutation (SNP) | VAF 46/125 reads (37%) | catalogued as COSV101010903; called by muse, mutect2, varscan2
- FBXW5 | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.226); catalogued as rs201344198; called by muse, mutect2, varscan2
- GREB1 | c.3145C>T p.R1049* | Nonsense Mutation (SNP) | VAF 43/628 reads (7%) | catalogued as rs373816391; called by muse, mutect2
- HAPLN2 | c.867G>T p.Q289H | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99660852; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1834G>T p.E612* | Nonsense Mutation (SNP) | VAF 52/142 reads (37%) | catalogued as COSV100079276; called by muse, mutect2, varscan2
- ITGA4 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 26/480 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99275555; called by muse, mutect2
- PLEKHH3 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 41/43 reads (95%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV52217452; called by muse, mutect2, varscan2
- POLG | c.1028C>A p.S343* | Nonsense Mutation (SNP) | VAF 60/118 reads (51%) | catalogued as COSV99174441; called by muse, mutect2, varscan2
- RBM27 | c.2876G>A p.G959E | Missense Mutation (SNP) | VAF 131/308 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV99505529; called by muse, mutect2, varscan2
- RP1L1 | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766702464, COSV101222837; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA3G | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1470559734, COSV99201790; called by muse, mutect2, varscan2
- SLC22A18 | c.937C>G p.L313V | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.07); catalogued as COSV100388626; called by muse, mutect2, varscan2
- TASOR2 | c.4682A>G p.N1561S | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV100049833; called by muse, mutect2, varscan2
- CALY | c.282G>A p.A94= | Silent (SNP) | VAF 87/175 reads (50%) | catalogued as rs199932152, COSV99428554; called by muse, mutect2, varscan2
- KCNG1 | c.213C>A p.G71= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as COSV100856937; called by muse, mutect2, varscan2
- SELENOO | c.987C>T p.G329= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as COSV101096425; called by muse, mutect2, varscan2
- SHC4 | c.420C>T p.S140= | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as COSV60110035; called by muse, mutect2, varscan2
- TAOK2 | c.1689G>A p.K563= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV99663594; called by muse, mutect2, varscan2
